Somatic mutation profile of tumor specimen MMRF_2817_1_BM_CD138pos (aliquot MMRF_2817_1_BM_CD138pos_T1_KHS5U_L15703) from MMRF case MMRF_2817, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: female; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 56.6 years (20,663 days).
Specimen MMRF_2817_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) dcef1fc1-b632-4007-8bd4-b3150b479116.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_2817_1_PB_WBC (Blood Derived Normal), aliquot MMRF_2817_1_PB_WBC_C3_KHS5U_L15749; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5b6f2300-3ad4-449a-8a82-c00448f65b5d

The open-access MAF lists 130 somatic variants for this specimen: 51 protein-altering or splice-affecting, 16 silent, 63 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 43, 3'UTR 40, Silent 16, Intron 12, 5'UTR 5, Nonsense Mutation 4, RNA 4, 3'Flank 2, Frame Shift Del 2, In Frame Del 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DIS3 | c.1463A>G p.D488G | Missense Mutation (SNP) | VAF 15/186 reads (8%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66706118, COSV66708289; called by muse, mutect2
- AR | c.1465G>T p.G489W | Missense Mutation (SNP) | VAF 50/118 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV65957346; called by muse, mutect2, varscan2
- CORIN | c.613G>A p.D205N | Missense Mutation (SNP) | VAF 75/309 reads (24%) | SIFT tolerated (0.16); PolyPhen benign (0.088); catalogued as COSV56688864; called by muse, mutect2, varscan2
- DMXL1 | c.7725A>C p.E2575D | Missense Mutation (SNP) | VAF 85/186 reads (46%) | SIFT tolerated (0.08); PolyPhen benign (0.115); catalogued as rs774885940; called by muse, mutect2, varscan2
- DUOX1 | c.1894C>T p.R632C | Missense Mutation (SNP) | VAF 40/78 reads (51%) | SIFT tolerated (0.11); PolyPhen benign (0.001); catalogued as rs766485051; called by muse, mutect2, varscan2
- EFTUD2 | c.2189G>A p.R730H | Missense Mutation (SNP) | VAF 41/102 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.746); catalogued as COSV53655180; called by muse, mutect2, varscan2
- ELK3 | c.143G>A p.R48Q | Missense Mutation (SNP) | VAF 13/242 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1388786729, COSV99957627; called by muse, mutect2
- H4C11 | c.205G>A p.D69N | Missense Mutation (SNP) | VAF 10/186 reads (5%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.954); catalogued as rs773266406; called by muse, mutect2
- IGHV1-69 | c.287G>C p.S96T | Missense Mutation (SNP) | VAF 175/193 reads (91%) | SIFT tolerated (0.09); PolyPhen benign (0.038); catalogued as rs1064565; called by muse, mutect2, varscan2
- IGLV5-45 | c.232C>T p.Q78* | Nonsense Mutation (SNP) | VAF 65/70 reads (93%) | catalogued as rs766606257; called by muse, mutect2, varscan2
- IGLV7-46 | c.140C>T p.A47V | Missense Mutation (SNP) | VAF 39/43 reads (91%) | SIFT tolerated (0.08); PolyPhen benign (0.024); catalogued as rs188705617; called by muse, mutect2, varscan2
- KCNA7 | c.778G>A p.E260K | Missense Mutation (SNP) | VAF 134/278 reads (48%) | SIFT tolerated (0.11); PolyPhen benign (0.2); catalogued as rs749212019, COSV55504682; called by muse, varscan2
- KLHL31 | c.322A>T p.I108F | Missense Mutation (SNP) | VAF 73/199 reads (37%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as rs202179716; called by muse, mutect2, varscan2
- MKS1 | c.1415G>A p.R472H | Missense Mutation (SNP) | VAF 91/169 reads (54%) | SIFT tolerated (0.34); PolyPhen benign (0.051); catalogued as rs772114886; called by muse, mutect2, varscan2
- OSBPL8 | c.218G>A p.G73D | Missense Mutation (SNP) | VAF 17/36 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV53881640; called by muse, mutect2, varscan2
- PCCA | c.1196G>A p.R399Q | Missense Mutation (SNP) | VAF 32/68 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1301904623, CM992385, COSV66194828; called by muse, mutect2, varscan2
- PCSK5 | c.5470G>A p.V1824I | Missense Mutation (SNP) | VAF 113/231 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs768735585, COSV101377228; called by muse, mutect2, varscan2
- PGR | c.529G>A p.G177R | Missense Mutation (SNP) | VAF 12/181 reads (7%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.927); catalogued as rs767280663; called by muse, mutect2
- SPEF1 | c.559G>A p.A187T | Missense Mutation (SNP) | VAF 91/210 reads (43%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.761); catalogued as rs1305590610; called by muse, mutect2, varscan2
- STRA6 | c.914C>T p.T305M | Missense Mutation (SNP) | VAF 43/94 reads (46%) | SIFT deleterious (0.02); PolyPhen benign (0.289); catalogued as rs756839205; called by muse, mutect2, varscan2
- SYNE1 | c.16909T>A p.F5637I (on ENST00000367255 / NM_182961.4; = p.F5566I on NM_033071.3) | Missense Mutation (SNP) | VAF 31/73 reads (42%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.49); catalogued as rs1267969296, COSV54932093; called by muse, mutect2, varscan2
- TEX14 | c.1495C>T p.R499* (on ENST00000240361 / NM_001201457.2; = p.R493* on NM_031272.5) | Nonsense Mutation (SNP) | VAF 92/193 reads (48%) | catalogued as rs749994851, COSV53624116; called by muse, mutect2, varscan2
- TFAP2B | c.1273C>G p.L425V | Missense Mutation (SNP) | VAF 118/240 reads (49%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.987); catalogued as rs1251432473; called by muse, mutect2, varscan2
- TTN | c.80438C>T p.P26813L (on ENST00000591111; = p.P19389L on NM_003319.4) | Missense Mutation (SNP) | VAF 81/171 reads (47%) | PolyPhen possibly damaging (0.643); catalogued as rs747983822; called by muse, mutect2, varscan2
- WNT2 | c.599G>A p.R200Q | Missense Mutation (SNP) | VAF 101/183 reads (55%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.895); catalogued as rs774137762; called by muse, mutect2, varscan2
- ZFHX4 | c.1846C>T p.P616S | Missense Mutation (SNP) | VAF 91/191 reads (48%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.998); catalogued as rs1397949913; called by muse, mutect2, varscan2
- ZNF234 | c.1840C>T p.H614Y | Missense Mutation (SNP) | VAF 87/191 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV70603190, COSV70603809; called by muse, mutect2, varscan2
- ARHGAP6 | c.1412A>C p.E471A | Missense Mutation (SNP) | VAF 48/92 reads (52%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.954); called by muse, mutect2, varscan2
- BCAS3 | c.2224C>T p.P742S (on ENST00000390652 / NM_001353144.2; = p.P727S on NM_017679.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 67/136 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- C8orf76 | c.205G>T p.E69* | Nonsense Mutation (SNP) | VAF 153/314 reads (49%) | called by muse, mutect2, varscan2
- CCDC85B | c.382G>A p.E128K | Missense Mutation (SNP) | VAF 52/102 reads (51%) | SIFT deleterious (0.02); PolyPhen benign (0.029); called by muse, mutect2, varscan2
- CLCA1 | c.508A>T p.N170Y | Missense Mutation (SNP) | VAF 8/160 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- CMTR2 | c.1564G>C p.A522P | Missense Mutation (SNP) | VAF 82/89 reads (92%) | SIFT deleterious (0); PolyPhen possibly damaging (0.617); called by muse, mutect2, varscan2
- DSCAM | c.5141C>A p.A1714D | Missense Mutation (SNP) | VAF 179/370 reads (48%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.63); called by muse, mutect2, varscan2
- IGKC | c.74_76del p.V26del | In Frame Del (DEL) | VAF 13/61 reads (21%) | called by pindel, varscan2
- IL1B | c.169T>A p.Y57N | Missense Mutation (SNP) | VAF 50/133 reads (38%) | SIFT tolerated (0.15); PolyPhen benign (0.116); called by muse, mutect2, varscan2
- ITGA6 | c.1788G>T p.Q596H (on ENST00000442250; = p.Q557H on NM_000210.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 79/204 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); called by muse, mutect2, varscan2
- KRT84 | c.1596del p.S533Afs*15 | Frame Shift Del (DEL) | VAF 26/57 reads (46%) | called by mutect2, varscan2
- MAOB | c.677G>A p.G226E | Missense Mutation (SNP) | VAF 34/91 reads (37%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.525); called by muse, mutect2, varscan2
- MGAM2 | c.4683A>C p.K1561N | Missense Mutation (SNP) | VAF 39/95 reads (41%) | SIFT tolerated (0.33); PolyPhen benign (0.053); called by muse, mutect2, varscan2
- MYH3 | c.3662A>C p.E1221A | Missense Mutation (SNP) | VAF 57/130 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- PCNX2 | c.1253C>A p.A418D | Missense Mutation (SNP) | VAF 33/481 reads (7%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.109); called by muse, mutect2
- RETNLB | c.286C>T p.Q96* | Nonsense Mutation (SNP) | VAF 122/234 reads (52%) | called by muse, mutect2, varscan2
- RNF40 | c.218T>G p.L73R | Missense Mutation (SNP) | VAF 10/150 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- TAF7L | c.1304T>A p.L435Q | Missense Mutation (SNP) | VAF 18/55 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- TMSB4X | c.-17+2T>C | Splice Site (SNP) | VAF 101/213 reads (47%) | called by muse, mutect2, varscan2
- TRIM42 | c.586T>G p.C196G | Missense Mutation (SNP) | VAF 23/302 reads (8%) | SIFT deleterious (0.04); PolyPhen benign (0.058); called by muse, mutect2
- TRO | c.4008del p.F1337Lfs*114 | Frame Shift Del (DEL) | VAF 176/364 reads (48%) | called by mutect2, varscan2
- ZNF343 | c.187A>G p.T63A | Missense Mutation (SNP) | VAF 112/236 reads (47%) | SIFT tolerated (0.84); PolyPhen benign (0.022); called by muse, varscan2
- ZNF7 | c.305C>T p.S102L | Missense Mutation (SNP) | VAF 34/126 reads (27%) | SIFT tolerated (0.32); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- ZPBP | c.343C>T p.R115C | Missense Mutation (SNP) | VAF 24/61 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.043); called by muse, mutect2, varscan2
- ADAMTS9 | c.25C>T p.L9= | Silent (SNP) | VAF 8/39 reads (21%) | called by muse, mutect2, varscan2
- ADGRL3 | c.138C>A p.P46= | Silent (SNP) | VAF 22/59 reads (37%) | catalogued as COSV72265460; called by muse, mutect2, varscan2
- CENPF | c.432A>C p.T144= | Silent (SNP) | VAF 72/238 reads (30%) | called by muse, mutect2, varscan2
- DNAH10 | c.5217C>T p.G1739= (on ENST00000409039; = p.G1678= on NM_207437.3) | Silent (SNP) | VAF 82/145 reads (57%) | called by muse, mutect2, varscan2
- DOCK2 | c.3441G>A p.E1147= | Silent (SNP) | VAF 30/170 reads (18%) | called by muse, mutect2, varscan2
- DUOX2 | c.2755C>T p.L919= | Silent (SNP) | VAF 119/210 reads (57%) | called by muse, mutect2, varscan2
- EFCC1 | c.1032A>G p.G344= | Silent (SNP) | VAF 74/159 reads (47%) | called by muse, mutect2, varscan2
- H2AC6 | c.129G>C p.R43= | Silent (SNP) | VAF 83/171 reads (49%) | called by muse, mutect2, varscan2
- IGLV7-43 | c.351G>A p.Q117= | Silent (SNP) | VAF 98/100 reads (98%) | catalogued as rs531882031; called by muse, mutect2, varscan2
- IGSF9B | c.2376G>A p.A792= | Silent (SNP) | VAF 41/105 reads (39%) | catalogued as rs746394518, COSV58074663; called by muse, mutect2, varscan2
- MEGF6 | c.927C>T p.C309= | Silent (SNP) | VAF 9/73 reads (12%) | catalogued as rs566231379, COSV53886322; called by muse, mutect2, varscan2
- MROH5 | c.1326C>T p.Y442= | Silent (SNP) | VAF 36/80 reads (45%) | catalogued as rs746334390; called by muse, mutect2, varscan2
- P2RY4 | c.600C>T p.F200= | Silent (SNP) | VAF 109/224 reads (49%) | called by muse, mutect2, varscan2
- PCSK9 | c.945C>T p.A315= | Silent (SNP) | VAF 38/70 reads (54%) | catalogued as rs1378856006; called by muse, mutect2, varscan2
- SHANK1 | c.6219G>A p.S2073= | Silent (SNP) | VAF 17/170 reads (10%) | catalogued as rs752181137, COSV53250557; called by muse, mutect2, varscan2
- THOC2 | c.723G>A p.P241= | Silent (SNP) | VAF 20/57 reads (35%) | catalogued as rs777252589; called by muse, mutect2, varscan2
- AC136604.1 | n.644G>A | RNA (SNP) | VAF 43/92 reads (47%) | catalogued as rs745332624; called by muse, mutect2, varscan2
- ATP11C | c.*1486T>G | 3'UTR (SNP) | VAF 35/80 reads (44%) | called by muse, mutect2, varscan2
- CACNA1C | c.4727-31C>T | Intron (SNP) | VAF 21/96 reads (22%) | called by muse, mutect2, varscan2
- CBL | c.*2598G>A | 3'UTR (SNP) | VAF 25/128 reads (20%) | called by muse, mutect2, varscan2
- CCDC157 | c.248+63C>T | Intron (SNP) | VAF 28/130 reads (22%) | called by muse, mutect2, varscan2
- CD9 | c.*183T>A | 3'UTR (SNP) | VAF 10/132 reads (8%) | called by muse, mutect2
- CKMT1B | c.*85C>G | 3'UTR (SNP) | VAF 18/412 reads (4%) | called by muse, mutect2
- CLEC14A | c.*411del | 3'UTR (DEL) | VAF 24/57 reads (42%) | called by mutect2, pindel, varscan2
- CNTN5 | c.*1621A>G | 3'UTR (SNP) | VAF 6/19 reads (32%) | called by muse, mutect2, varscan2
- CSMD3 | c.*1152T>G | 3'UTR (SNP) | VAF 21/74 reads (28%) | called by muse, mutect2, varscan2
- CTBP2P4 | n.840G>T | RNA (SNP) | VAF 26/56 reads (46%) | called by muse, mutect2, varscan2
- DSEL | c.*1358A>G | 3'UTR (SNP) | VAF 36/121 reads (30%) | called by muse, mutect2, varscan2
- ECM2 | c.481+880A>T | Intron (SNP) | VAF 54/107 reads (50%) | called by muse, mutect2, varscan2
- EMX2 | c.-277T>A | 5'UTR (SNP) | VAF 57/130 reads (44%) | called by muse, mutect2, varscan2
- ENPP3 | c.872+89C>A | Intron (SNP) | VAF 37/81 reads (46%) | called by muse, mutect2, varscan2
- EPHA3 | c.*97G>T | 3'UTR (SNP) | VAF 41/84 reads (49%) | called by muse, mutect2, varscan2
- FAR1 | c.1128-787C>G | Intron (SNP) | VAF 4/58 reads (7%) | called by muse, mutect2
- FGG | c.*126A>G | 3'UTR (SNP) | VAF 44/72 reads (61%) | called by muse, mutect2, varscan2
- FSTL4 | c.*1806del | 3'UTR (DEL) | VAF 35/84 reads (42%) | called by mutect2, varscan2
- GPR45 | c.*444C>T | 3'UTR (SNP) | VAF 50/106 reads (47%) | called by muse, varscan2
- GRB10 | c.*2130C>T | 3'UTR (SNP) | VAF 41/94 reads (44%) | catalogued as rs1478775756; called by muse, mutect2, varscan2
- HS3ST3B1 | c.*1067C>G | 3'UTR (SNP) | VAF 50/119 reads (42%) | called by muse, mutect2, varscan2
- IGLV1-41 | n.210G>A | RNA (SNP) | VAF 71/76 reads (93%) | catalogued as rs527833904; called by muse, mutect2, varscan2
- IRS2 | c.*960G>C | 3'UTR (SNP) | VAF 10/105 reads (10%) | called by muse, mutect2, varscan2
- KCTD3 | c.*931G>A | 3'UTR (SNP) | VAF 18/94 reads (19%) | catalogued as COSV99378977, COSV99379270; called by muse, mutect2, varscan2
- KNL1 | c.*966G>T | 3'UTR (SNP) | VAF 8/25 reads (32%) | called by muse, mutect2
- LMBR1 | c.*3282C>G | 3'UTR (SNP) | VAF 20/54 reads (37%) | called by muse, mutect2, varscan2
- MAN1A2 | c.*2833G>C | 3'UTR (SNP) | VAF 6/32 reads (19%) | called by muse, mutect2
- MAP3K20 | c.988-5663G>C | Intron (SNP) | VAF 49/95 reads (52%) | called by muse, mutect2, varscan2
- MIR5195 | n.68C>T | RNA (SNP) | VAF 53/107 reads (50%) | called by muse, mutect2, varscan2
- MLPH | c.*190G>A | 3'UTR (SNP) | VAF 59/108 reads (55%) | called by muse, mutect2, varscan2
- MSL1 | c.1424-133A>T | Intron (SNP) | VAF 12/26 reads (46%) | called by muse, mutect2, varscan2
- MUCL3 | c.947-864G>T | Intron (SNP) | VAF 295/611 reads (48%) | called by muse, mutect2, varscan2
- MYO10 | c.*985del | 3'UTR (DEL) | VAF 47/101 reads (47%) | called by mutect2, pindel, varscan2
- NKRF | c.*301A>T | 3'UTR (SNP) | VAF 8/100 reads (8%) | called by muse, mutect2
- NUDT16L1 | c.*212G>T | 3'UTR (SNP) | VAF 50/104 reads (48%) | called by muse, mutect2, varscan2
- OGG1 | c.*252T>A | 3'UTR (SNP) | VAF 9/70 reads (13%) | called by muse, mutect2, varscan2
- OSR2 | c.-76C>T | 5'UTR (SNP) | VAF 36/333 reads (11%) | called by muse, mutect2, varscan2
- OVGP1 | c.1021-143A>T | Intron (SNP) | VAF 27/54 reads (50%) | called by muse, mutect2, varscan2
- PARVA | c.*2267A>C | 3'UTR (SNP) | VAF 29/61 reads (48%) | called by muse, mutect2, varscan2
- PLEKHO1 | c.*509G>A | 3'UTR (SNP) | VAF 7/67 reads (10%) | called by muse, mutect2, varscan2
- PXK | c.*1116C>G | 3'UTR (SNP) | VAF 7/15 reads (47%) | called by muse, mutect2, varscan2
- RAP2A | c.*122A>T | 3'UTR (SNP) | VAF 5/73 reads (7%) | called by muse, mutect2
- SLC27A5 | c.1183-13G>A | Intron (SNP) | VAF 6/112 reads (5%) | called by muse, mutect2
- SLC35F1 | c.*2708dup | 3'UTR (INS) | VAF 9/67 reads (13%) | catalogued as rs1472962784; called by mutect2, pindel, varscan2
- SLC45A4 | c.*4312C>T | 3'UTR (SNP) | VAF 18/149 reads (12%) | called by muse, mutect2
- SLC7A9 | c.236-88G>A | Intron (SNP) | VAF 19/37 reads (51%) | catalogued as rs1168546832; called by muse, mutect2, varscan2
- SLCO1B3-SLCO1B7 | c.*31T>A | 3'UTR (SNP) | VAF 93/191 reads (49%) | catalogued as rs1221768279; called by muse, mutect2, varscan2
- ST8SIA1 | c.*177A>G | 3'UTR (SNP) | VAF 62/131 reads (47%) | called by muse, mutect2, varscan2
- STEAP3 | c.*2059G>C | 3'UTR (SNP) | VAF 12/103 reads (12%) | called by muse, mutect2, varscan2
- SV2C | c.*2053C>A | 3'UTR (SNP) | VAF 19/89 reads (21%) | called by muse, mutect2, varscan2
- TACC1 | c.-172C>A | 5'UTR (SNP) | VAF 10/88 reads (11%) | called by muse, mutect2, varscan2
- TEAD1 | c.*582del | 3'UTR (DEL) | VAF 33/81 reads (41%) | catalogued as rs905683372; called by mutect2, varscan2
- TLR2 | c.-1232G>A | 5'UTR (SNP) | VAF 27/55 reads (49%) | catalogued as rs540154178; called by muse, mutect2, varscan2
- TMEM218 | chr11:125096946 T>C | 3'Flank (SNP) | VAF 27/61 reads (44%) | called by muse, mutect2, varscan2
- TRIM63 | c.*502G>T | 3'UTR (SNP) | VAF 57/147 reads (39%) | called by muse, mutect2
- TRO | c.*44A>C | 3'UTR (SNP) | VAF 87/181 reads (48%) | called by muse, mutect2, varscan2
- TTPA | c.*334A>C | 3'UTR (SNP) | VAF 32/76 reads (42%) | called by muse, mutect2, varscan2
- TXNDC11 | c.-21G>T | 5'UTR (SNP) | VAF 49/105 reads (47%) | catalogued as rs1353737979; called by muse, mutect2, varscan2
- TXNRD2 | c.450-37A>T | Intron (SNP) | VAF 110/223 reads (49%) | called by muse, varscan2
- XPO4 | c.*1868C>T | 3'UTR (SNP) | VAF 26/120 reads (22%) | called by muse, mutect2, varscan2
- ZBTB43 | chr9:126837725 G>T | 3'Flank (SNP) | VAF 65/138 reads (47%) | catalogued as rs1288569477; called by muse, mutect2, varscan2
- ZNF324 | c.*95C>G | 3'UTR (SNP) | VAF 15/32 reads (47%) | called by muse, mutect2
